Surgical pathology report (de-identified scan), TCGA case TCGA-EC-A1NJ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Asterand, specimen TCGA-EC-A1NJ-01A (Primary Tumor).

100-0-3

adenocarcinoma, endometrioid, nos 8380/3

Site: Endometrium c54.1

3/8/11 *hw*

Pathology Reports

Requisition #

Case ID	OpenClinica Formatted Path Report Subject ID	UTERUS TISSUE CHECKLIST	Laterality	Date of Procurement
		Specimen type: Hysterectomy Tumor site: Uterus Tumor size: 3 x 2.5 x 1 cm Histologic type: Endometrioid adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Less than 1/2 myometrium Lymph nodes: Not specified Lymphatic invasion: Not specified Venous invasion: Not specified Extent of myometrial invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None	NA	

Source: NCI Genomic Data Commons file 57a90b69-a6a5-4635-9fba-d8f5132f6f73 (TCGA-EC-A1NJ.8E02F7D6-EBE4-46CB-B05C-B41FDCDC1141.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).